Somatic mutation profile of tumor specimen C3L-02621-01 (aliquot CPT0201830007) from CPTAC case C3L-02621, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.9 years (25,156 days).
Specimen C3L-02621-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f004981e-68ba-4a99-b014-2f8cfbde980c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02621-31 (Blood Derived Normal), aliquot CPT0201970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e6c7d12-fbe2-4a2f-9503-70d201f42b8b

The open-access MAF lists 411 somatic variants for this specimen: 276 protein-altering or splice-affecting, 92 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 92, Nonsense Mutation 21, RNA 15, Intron 12, Splice Site 9, Frame Shift Del 7, 3'UTR 6, 5'Flank 5, 5'UTR 4, Splice Region 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.1503+1G>C p.X501_splice | Splice Site (SNP) | VAF 66/415 reads (16%) | catalogued as rs1554396615; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 125/626 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50287934; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 27/233 reads (12%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADGRB3 | c.3091G>A p.A1031T | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs775555129, COSV53235954, COSV53255477; called by muse, mutect2
- ADGRG3 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs746345577; called by muse, mutect2
- ADGRG4 | c.1646C>A p.S549* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV54959465; called by muse, mutect2, varscan2
- AHDC1 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.7); catalogued as COSV55939125; called by muse, mutect2, varscan2
- ANG | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs141398857, CM1110462, COSV100390908; called by muse, mutect2, varscan2
- ANGPT1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs568159633, COSV52456443; called by muse, mutect2
- ANHX | c.367T>C p.C123R | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV69293577; called by muse, mutect2
- APBB2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 32/340 reads (9%) | catalogued as COSV55951286; called by muse, mutect2
- APOBEC3H | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763596358; called by muse, mutect2
- ATRNL1 | c.3703G>A p.V1235I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV100370516; called by muse, mutect2, varscan2
- BAK1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs531594065; called by muse, mutect2
- BCL9L | c.3273G>A p.M1091I | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52688571; called by muse, mutect2, varscan2
- BICC1 | c.2225T>C p.M742T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1375812023; called by muse, mutect2
- CBX2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs782550309; called by muse, mutect2, varscan2
- CCDC78 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs759668390; called by muse, mutect2
- CD9 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 22/233 reads (9%) | catalogued as COSV50531724; called by muse, mutect2, varscan2
- CDH19 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs570335688; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 81/711 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CFHR1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 41/346 reads (12%) | catalogued as COSV57626612; called by muse, mutect2, varscan2
- CFTR | c.3344C>A p.T1115N | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs1200739289; called by muse, mutect2, varscan2
- CHRM2 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV100280556, COSV57773131, COSV57785401; called by muse, mutect2
- CLCA4 | c.395A>C p.H132P | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1433159200; called by muse, mutect2
- CLDN17 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV99729459; called by muse, mutect2
- CLEC12A | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs866680135; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV62150646; called by muse, mutect2
- COL4A4 | c.1958G>T p.R653M | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100307264; called by muse, mutect2
- CSMD3 | c.3922G>A p.G1308S (on ENST00000297405 / NM_001363185.1; = p.G1204S on NM_052900.3) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV52107783; called by muse, mutect2
- CSN1S1 | c.556T>C p.*186Rext*3 | Nonstop Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs1185341014; called by muse, varscan2
- DOCK10 | c.3974G>T p.R1325L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV51347560; called by muse, mutect2
- ETNK2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs751988639, COSV65820560; called by muse, mutect2
- FAM83D | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs773179759; called by muse, mutect2
- FER | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 12/186 reads (6%) | catalogued as rs1463264391, COSV99812095; called by muse, mutect2
- FOXI2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs756295119; called by muse, mutect2, varscan2
- FZR1 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100281365; called by muse, mutect2
- GCN1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs780184585; called by muse, mutect2
- GGT5 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374962171; called by muse, mutect2, varscan2
- GGTLC1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 82/814 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs760906005; called by muse, mutect2, varscan2
- GRIN2A | c.2554G>A p.V852M | Missense Mutation (SNP) | VAF 63/606 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); catalogued as rs150316865, COSV58028543; called by muse, mutect2, varscan2
- GRIN2B | c.3685G>T p.V1229L | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as COSV74205450; called by muse, mutect2, varscan2
- GRM1 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 64/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557036170; called by muse, mutect2, varscan2
- H1-3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs145654336; called by muse, mutect2, varscan2
- HEPHL1 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV59889262; called by muse, mutect2, varscan2
- HK3 | c.1946G>C p.R649P | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99459409; called by muse, mutect2, varscan2
- HMCN1 | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.13); catalogued as COSV99623387; called by muse, mutect2, varscan2
- HNRNPU | c.967G>A p.D323N (on ENST00000283179; = p.D385N on NM_004501.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51689011; called by muse, mutect2, varscan2
- IFNAR2 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV59746620; called by muse, mutect2, varscan2
- IGFBP3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV99298384; called by muse, mutect2
- KRT3 | c.1717G>C p.G573R | Missense Mutation (SNP) | VAF 67/530 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); catalogued as rs867046839; called by muse, mutect2, varscan2
- LCT | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 43/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51555233; called by muse, mutect2
- LECT2 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1180043451; called by muse, mutect2
- MGAM | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101516582; called by muse, mutect2, varscan2
- MUC16 | c.38219A>G p.K12740R | Missense Mutation (SNP) | VAF 86/500 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.028); catalogued as rs761416634, COSV67481996; called by muse, mutect2, varscan2
- MUC17 | c.7411T>A p.S2471T | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV60279144; called by muse, mutect2
- NALCN | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV99217365; called by muse, mutect2
- NKAIN3 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs756854897, COSV60674683; called by muse, mutect2, varscan2
- NKAPL | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV59199744; called by muse, mutect2
- NLRP10 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 41/319 reads (13%) | catalogued as COSV100149716; called by muse, mutect2, varscan2
- NME8 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV52251944; called by muse, mutect2, varscan2
- NPFFR1 | c.1046G>T p.C349F | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV53332149; called by muse, mutect2
- OBSCN | c.10540G>T p.D3514Y | Missense Mutation (SNP) | VAF 68/683 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52825848; called by muse, mutect2
- OR6N1 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV58647423, COSV58647736; called by muse, mutect2, varscan2
- OR7E24 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101509628; called by muse, mutect2
- PARD3B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs772515904, COSV100594735; called by muse, mutect2, varscan2
- PCDHGA6 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs1277096139; called by muse, mutect2, varscan2
- PKHD1 | c.10555C>A p.L3519M | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV64388077; called by muse, mutect2, varscan2
- PLAC8 | c.64dup p.Q22Pfs*11 | Frame Shift Ins (INS) | VAF 30/284 reads (11%) | catalogued as rs1287583575; called by mutect2, pindel
- POTEC | c.925del p.L309Sfs*12 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as COSV62802478; called by mutect2, varscan2
- PRRT4 | c.404G>C p.R135P | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.159); catalogued as rs1429824325; called by muse, mutect2
- PTGER3 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100139113; called by muse, mutect2
- PTPRC | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs746435286; called by muse, mutect2, varscan2
- RASL12 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs748653739, COSV99584802; called by muse, mutect2, varscan2
- RETREG1 | c.1304C>A p.A435E (on ENST00000306320 / NM_001034850.2; = p.A294E on NM_019000.4) | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs961559063; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 29/227 reads (13%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RYR2 | c.7240G>T p.G2414* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as COSV63670172; called by muse, mutect2, varscan2
- SELENOF | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV59356682; called by muse, mutect2
- SIGLEC10 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.168); catalogued as rs762968568; called by muse, mutect2
- SLC12A3 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs79351185, CM002107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A8 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1447864797; called by muse, mutect2
- SLC6A7 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1024405630; called by muse, mutect2
- SORCS1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs370679881, COSV53857213; called by muse, mutect2, varscan2
- ST3GAL5 | c.622G>C p.A208P (on ENST00000377332; = p.A248P on NM_003896.4) | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60386255; called by muse, mutect2
- TAAR9 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV71512191; called by muse, mutect2
- TGFBR2 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM064337, CM105037; called by muse, mutect2, varscan2
- TOGARAM1 | c.3147A>G p.I1049M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as rs761767787; called by mutect2, varscan2
- TP53BP1 | c.4006C>G p.P1336A | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs202077092; called by muse, mutect2, varscan2
- TP53BP2 | c.3031G>A p.V1011I (on ENST00000343537 / NM_001031685.3; = p.V882I on NM_005426.2) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1329437700; called by muse, mutect2
- TRBV27 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs778277252; called by muse, mutect2
- TTN | c.36451G>A p.V12151M (on ENST00000591111; = p.V4727M on NM_003319.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | PolyPhen probably damaging (0.964); catalogued as rs1445036438; called by muse, mutect2
- UGT1A5 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 34/450 reads (8%) | catalogued as COSV59389105; called by muse, mutect2
- USF2 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99723123; called by muse, mutect2
- VRTN | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV56444010; called by muse, mutect2, varscan2
- ZNF337 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV53320176; called by muse, mutect2, varscan2
- ZNF347 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs146644074; called by muse, mutect2
- ZNF621 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573787592; called by muse, mutect2, varscan2
- ABCA13 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ACACB | c.6655T>A p.Y2219N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAD8 | c.947A>G p.Q316R | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ACE | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACSM1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 53/496 reads (11%) | called by muse, mutect2, varscan2
- ADAM8 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS12 | c.3619G>T p.E1207* | Nonsense Mutation (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- ADCY10 | c.1135A>T p.I379F | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ADGRB1 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 31/444 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.231); called by muse, mutect2
- ADGRG3 | c.709del p.V237Sfs*13 | Frame Shift Del (DEL) | VAF 45/317 reads (14%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.3101G>A p.C1034Y | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AHRR | c.1396A>G p.R466G | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ALMS1 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.073); called by muse, mutect2
- ALPK1 | c.2330C>T p.T777I | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPL | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 58/504 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, varscan2
- APEH | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 65/534 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOBEC3B | c.936C>G p.I312M | Missense Mutation (SNP) | VAF 82/1620 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATMIN | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL11A | c.661G>T p.A221S (on ENST00000335712 / NM_001365609.1; = p.A255S on NM_018014.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BHLHE22 | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BIRC6 | c.3857A>G p.K1286R | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMT2 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- BRWD3 | c.3538A>T p.T1180S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- C4orf17 | c.384T>A p.N128K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- C8orf34 | c.1168A>T p.N390Y | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, varscan2
- CCDC168 | c.13490A>G p.Y4497C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD1E | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, varscan2
- CELF4 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CEP164 | c.3106G>T p.A1036S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CEP295NL | c.1376A>T p.N459I | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CFAP46 | c.4115A>G p.E1372G | Missense Mutation (SNP) | VAF 29/581 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- COL11A2 | c.5140T>A p.S1714T (on ENST00000341947 / NM_080680.3; = p.S1607T on NM_080679.2) | Missense Mutation (SNP) | VAF 88/679 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- COL24A1 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD3 | c.8082T>A p.C2694* | Nonsense Mutation (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2
- CSMD3 | c.5525T>A p.L1842Q (on ENST00000297405 / NM_001363185.1; = p.L1738Q on NM_052900.3) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CST11 | c.333+1G>C p.X111_splice | Splice Site (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- CST5 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CTAGE6 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2
- DPP3 | c.1830C>G p.I610M | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPP4 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF2AK3 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 24/295 reads (8%) | called by muse, mutect2
- ELF4 | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ERICH3 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ERICH3 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- ERV3-1 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO38 | c.293_294del p.L98* | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- FCER1A | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- FOXK2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 59/503 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FRMPD4 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FRY | c.8453G>T p.G2818V | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABBR1 | c.499C>A p.R167= | Splice Region (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- GAD1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GALNT5 | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLYR1 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 35/399 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2
- GREB1 | c.4197G>A p.W1399* | Nonsense Mutation (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- GRIN2B | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 46/441 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GTF2B | c.265G>T p.G89* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- HCN1 | c.1187T>C p.L396S | Missense Mutation (SNP) | VAF 47/643 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- HECTD4 | c.9959C>A p.A3320D | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); called by muse, mutect2
- HERC2 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HRH3 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- HS2ST1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.203); called by muse, varscan2
- HTR2B | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2
- IFNA7 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); called by muse, varscan2
- IGHG2 | c.243C>A p.Y81* | Nonsense Mutation (SNP) | VAF 114/543 reads (21%) | called by muse, mutect2, varscan2
- KANK2 | c.2335G>T p.A779S (on ENST00000586659 / NM_001379562.1; = p.A787S on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/565 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KEAP1 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KHDC1 | c.646G>C p.V216L (on ENST00000370384 / NM_001251874.2; = p.V143L on NM_030568.5) | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2
- KNDC1 | c.4487G>T p.R1496L | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT25 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP19-7 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.067); called by muse, mutect2
- LCE1A | c.265A>C p.S89R | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.775); called by muse, mutect2
- LINGO3 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- LTBP4 | c.2024G>A p.C675Y (on ENST00000308370 / NM_001042544.1; = p.C638Y on NM_003573.2) | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LY9 | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.8912A>G p.N2971S | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, varscan2
- MARS1 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAVS | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MDGA2 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIDEAS | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 26/249 reads (10%) | called by muse, varscan2
- MKRN1 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MMADHC | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2
- MUC5B | c.1698C>A p.N566K | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO1G | c.1929del p.Y644Tfs*10 | Frame Shift Del (DEL) | VAF 27/258 reads (10%) | called by mutect2, pindel, varscan2
- MYO5B | c.3907G>T p.A1303S | Missense Mutation (SNP) | VAF 85/807 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- NAV3 | c.4607C>G p.S1536* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- NCK1 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP12 | c.2146A>C p.I716L | Missense Mutation (SNP) | VAF 57/794 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.142); called by muse, mutect2
- NMRK2 | c.563A>C p.Q188P | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NPC1L1 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 66/637 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NPTXR | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 47/569 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.25); called by muse, mutect2
- NRXN1 | c.3067A>C p.K1023Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, varscan2
- OGA | c.1984+3A>T | Splice Region (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- OPA1 | c.1608+5G>T | Splice Region (SNP) | VAF 59/346 reads (17%) | called by muse, mutect2, varscan2
- OR2T27 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR2T3 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR52B6 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- OR52H1 | c.802C>G p.H268D (on ENST00000322653; = p.H274D on NM_001005289.1) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- OR52J3 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- OR7G1 | c.458C>G p.T153S | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- P2RX4 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARP9 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATJ | c.5138G>A p.G1713E | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA12 | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX2 | c.5948G>T p.S1983I | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PFKFB2 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 19/258 reads (7%) | PolyPhen possibly damaging (0.829); called by muse, mutect2
- PHLPP1 | c.4624G>T p.D1542Y | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLPPR3 | c.1380C>G p.D460E (on ENST00000520876 / NM_001270366.2; = p.D488E on NM_024888.2) | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIP | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PON1 | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 90/448 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by mutect2, varscan2
- POTEE | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 84/863 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- POTEI | c.2511G>T p.Q837H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PRDM9 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 70/582 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMD3 | c.1528-1G>A p.X510_splice | Splice Site (SNP) | VAF 39/313 reads (12%) | called by muse, mutect2, varscan2
- PTPN13 | c.207A>C p.E69D | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PTPRB | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.148); called by muse, varscan2
- RALGAPA2 | c.4902G>T p.E1634D | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- RASGRF1 | c.2261G>T p.R754L | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RBM46 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RGS21 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- RIMS1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RPL13 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, varscan2
- RRP9 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, varscan2
- SBK3 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- SCML1 | c.413G>A p.S138N (on ENST00000380041 / NM_001037540.3; = p.S111N on NM_006746.6) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCN3A | c.4989C>A p.F1663L | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SELP | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERINC2 | c.962C>G p.A321G (on ENST00000373709 / NM_178865.5; = p.A325G on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SHISA3 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC13A1 | c.117C>A p.Y39* | Nonsense Mutation (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2, varscan2
- SLC22A12 | c.1172C>A p.P391Q | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); called by muse, mutect2
- SLC22A2 | c.420C>G p.N140K | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SLC25A38 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SP110 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- SPATA13 | c.360dup p.E121* | Frame Shift Ins (INS) | VAF 26/232 reads (11%) | called by mutect2, pindel, varscan2
- SPATS2L | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- STARD9 | c.10963G>A p.D3655N | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SYNE1 | c.18667T>A p.W6223R (on ENST00000367255 / NM_182961.4; = p.W6152R on NM_033071.3) | Missense Mutation (SNP) | VAF 70/784 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TANGO2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- TAX1BP1 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- TAX1BP1 | c.1267A>C p.K423Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.139); called by muse, mutect2
- TCEAL5 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TCP11L1 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDP1 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 44/380 reads (12%) | called by muse, mutect2, varscan2
- TENM4 | c.4459G>C p.D1487H | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TKTL2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TMEM108 | c.492G>T p.R164S | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- TMEM232 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2
- TMEM41A | c.273+2T>A p.X91_splice | Splice Site (SNP) | VAF 40/468 reads (9%) | called by muse, mutect2
- TNFAIP8L3 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.049); called by muse, mutect2
- TNN | c.3045+2T>C p.X1015_splice | Splice Site (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- TRABD2B | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPC7 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TRPM6 | c.2398T>C p.Y800H | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TSR2 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTC38 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by mutect2, varscan2
- TTN | c.78224T>G p.L26075R (on ENST00000591111; = p.L18651R on NM_003319.4) | Missense Mutation (SNP) | VAF 31/193 reads (16%) | PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TTN | c.36378G>C p.K12126N (on ENST00000591111; = p.K4702N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | PolyPhen probably damaging (0.961); called by muse, mutect2
- TVP23A | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- TXNDC16 | c.1618+1G>C p.X540_splice | Splice Site (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TXNRD1 | c.92-2A>G p.X31_splice | Splice Site (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- UBE2M | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- UBXN7 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.116); called by muse, mutect2
- UHRF1BP1L | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- USH1G | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USP34 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2
- USP49 | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VCAN | c.10064-3T>C | Splice Region (SNP) | VAF 30/297 reads (10%) | called by muse, mutect2, varscan2
- WDR27 | c.1115C>G p.A372G | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- WDR3 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- WNT8B | c.1003C>A p.R335S | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZFR2 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.222); called by muse, mutect2
- ZIC1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZKSCAN4 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF280A | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZNF341 | c.2110_2111del p.A704Pfs*65 (on ENST00000375200 / NM_001282935.1; = p.A697Pfs*65 on NM_032819.4) | Frame Shift Del (DEL) | VAF 30/232 reads (13%) | called by pindel, varscan2
- ZNF835 | c.343T>G p.C115G | Missense Mutation (SNP) | VAF 113/683 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF91 | c.1979G>T p.C660F | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF98 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- ABLIM1 | c.465G>A p.G155= | Silent (SNP) | VAF 33/236 reads (14%) | catalogued as rs745788414; called by muse, mutect2, varscan2
- APOA4 | c.1018T>C p.L340= | Silent (SNP) | VAF 74/551 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.450G>A p.G150= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- ASAP3 | c.1194C>T p.S398= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as rs762296900; called by muse, mutect2, varscan2
- ATP8B3 | c.1893C>G p.V631= | Silent (SNP) | VAF 16/307 reads (5%) | called by muse, mutect2
- BNIP3 | c.705G>T p.L235= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- C20orf194 | c.1791C>G p.T597= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2
- CCDC106 | c.609C>T p.F203= | Silent (SNP) | VAF 42/414 reads (10%) | called by muse, mutect2
- CEP295 | c.2100C>G p.T700= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.300C>G p.T100= | Silent (SNP) | VAF 73/405 reads (18%) | called by muse, mutect2, varscan2
- CPAMD8 | c.3183C>T p.T1061= (on ENST00000651564; = p.T1014= on NM_015692.5) | Silent (SNP) | VAF 39/468 reads (8%) | called by muse, mutect2
- CRB1 | c.4167C>G p.S1389= | Silent (SNP) | VAF 38/469 reads (8%) | called by muse, mutect2
- CYP26B1 | c.1314C>A p.V438= | Silent (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- CYP3A4 | c.24C>T p.A8= | Silent (SNP) | VAF 60/369 reads (16%) | called by muse, mutect2, varscan2
- DENND2C | c.2184G>T p.L728= (on ENST00000393274 / NM_001256404.2; = p.L671= on NM_198459.4) | Silent (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2
- DNAAF2 | c.1254G>A p.P418= | Silent (SNP) | VAF 41/293 reads (14%) | called by muse, mutect2, varscan2
- DSTYK | c.1488A>G p.E496= | Silent (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- EDEM3 | c.2106G>A p.V702= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as rs1361601838; called by muse, mutect2
- EPC1 | c.1191T>C p.D397= | Silent (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- ERBB4 | c.2448A>T p.G816= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- ESPN | c.462G>A p.L154= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs770342857; called by muse, mutect2
- EXOC4 | c.9A>T p.A3= | Silent (SNP) | VAF 51/293 reads (17%) | called by muse, mutect2, varscan2
- FBN3 | c.2865G>A p.P955= | Silent (SNP) | VAF 63/641 reads (10%) | catalogued as rs749171861, COSV54467103; called by muse, mutect2, varscan2
- FGGY | c.1641C>T p.I547= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1470091609; called by muse, mutect2
- GALK2 | c.927G>A p.E309= | Silent (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2
- GCAT | c.33C>T p.L11= | Silent (SNP) | VAF 73/408 reads (18%) | called by muse, mutect2, varscan2
- GDF10 | c.1359C>T p.V453= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs376782261; called by muse, mutect2, varscan2
- GPR12 | c.108A>G p.V36= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs767659537; called by muse, mutect2, varscan2
- HGF | c.1578G>A p.E526= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV55949285; called by muse, mutect2, varscan2
- HIP1R | c.2727G>A p.E909= | Silent (SNP) | VAF 35/334 reads (10%) | called by muse, mutect2, varscan2
- HOXD1 | c.216G>T p.P72= | Silent (SNP) | VAF 26/197 reads (13%) | called by muse, mutect2, varscan2
- HSPA14 | c.33C>T p.T11= | Silent (SNP) | VAF 36/351 reads (10%) | called by muse, mutect2, varscan2
- INSL3 | c.39G>A p.L13= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- INSYN2B | c.165C>T p.D55= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs748170159; called by muse, mutect2, varscan2
- KCNQ3 | c.1905G>A p.K635= | Silent (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- KIAA1217 | c.2580C>G p.G860= | Silent (SNP) | VAF 65/585 reads (11%) | called by muse, mutect2, varscan2
- KMO | c.177T>G p.S59= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- LGR4 | c.1735T>C p.L579= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- LILRB5 | c.81C>T p.P27= | Silent (SNP) | VAF 44/277 reads (16%) | called by muse, mutect2, varscan2
- LIN9 | c.186G>T p.P62= | Silent (SNP) | VAF 29/261 reads (11%) | called by muse, mutect2, varscan2
- LPA | c.5112G>T p.P1704= | Silent (SNP) | VAF 49/530 reads (9%) | catalogued as rs770035632, COSV100306546, COSV100307989; called by muse, mutect2
- LYZL6 | c.339A>G p.A113= | Silent (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- MAGEA12 | c.591C>T p.P197= | Silent (SNP) | VAF 93/401 reads (23%) | called by muse, mutect2, varscan2
- MISP | c.1179C>T p.L393= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- MTARC1 | c.543G>T p.V181= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- MUC12 | c.14403C>T p.Y4801= (on ENST00000379442; = p.Y4658= on NM_001164462.1) | Silent (SNP) | VAF 104/563 reads (18%) | called by muse, mutect2, varscan2
- MYOM2 | c.1926G>T p.L642= | Silent (SNP) | VAF 25/240 reads (10%) | catalogued as rs1445995825; called by muse, mutect2, varscan2
- NAPRT | c.1338A>T p.P446= | Silent (SNP) | VAF 37/303 reads (12%) | called by muse, mutect2, varscan2
- NCAN | c.531G>A p.E177= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- NLGN1 | c.387C>A p.V129= | Silent (SNP) | VAF 24/267 reads (9%) | called by muse, mutect2
- OBSCN | c.10539G>C p.A3513= | Silent (SNP) | VAF 68/684 reads (10%) | called by muse, mutect2
- OPTC | c.66C>A p.L22= | Silent (SNP) | VAF 58/533 reads (11%) | called by muse, mutect2, varscan2
- OR10X1 | c.687C>A p.L229= | Silent (SNP) | VAF 19/320 reads (6%) | called by muse, mutect2
- OR14A16 | c.480C>G p.G160= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as COSV62927461; called by muse, mutect2
- OR2M2 | c.816G>A p.K272= | Silent (SNP) | VAF 34/496 reads (7%) | catalogued as COSV62898607; called by muse, mutect2
- OR5AR1 | c.345G>T p.L115= | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as COSV100265532; called by muse, mutect2, varscan2
- PCDHB6 | c.1905G>A p.K635= | Silent (SNP) | VAF 81/779 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1869G>A p.T623= | Silent (SNP) | VAF 62/509 reads (12%) | catalogued as rs757328487, COSV100965913; called by muse, mutect2, varscan2
- PCDHGA6 | c.1932G>T p.V644= | Silent (SNP) | VAF 63/598 reads (11%) | called by muse, mutect2, varscan2
- PCLO | c.9468A>T p.V3156= | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- PEG3 | c.2703T>C p.R901= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- PEX5 | c.486A>G p.E162= | Silent (SNP) | VAF 47/409 reads (11%) | catalogued as rs1267734281; called by muse, varscan2
- PIF1 | c.1782G>A p.L594= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as rs1479940331; called by muse, mutect2, varscan2
- PLCG2 | c.2577C>T p.N859= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs747043855, COSV63875441; ClinVar: likely benign; called by muse, mutect2, varscan2
- POU3F4 | c.921G>A p.E307= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV64537927; called by muse, mutect2, varscan2
- PTCH2 | c.1608C>T p.G536= | Silent (SNP) | VAF 60/610 reads (10%) | called by muse, mutect2
- PTGFR | c.1026A>G p.L342= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- RTN2 | c.1014A>G p.G338= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV55595588; called by muse, mutect2, varscan2
- RYR1 | c.8910T>A p.S2970= | Silent (SNP) | VAF 80/435 reads (18%) | called by muse, mutect2, varscan2
- SAMSN1 | c.504C>A p.A168= | Silent (SNP) | VAF 45/420 reads (11%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.720C>T p.T240= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs372958477, COSV99346418; called by muse, mutect2, varscan2
- SIX2 | c.432G>T p.A144= | Silent (SNP) | VAF 38/332 reads (11%) | catalogued as COSV57391541; called by muse, mutect2, varscan2
- SLC5A5 | c.1404C>T p.P468= | Silent (SNP) | VAF 59/526 reads (11%) | catalogued as rs1297886557; called by muse, mutect2, varscan2
- SOGA3 | c.54C>T p.P18= | Silent (SNP) | VAF 54/574 reads (9%) | catalogued as rs1562390033, COSV100846877; called by muse, mutect2
- TAOK2 | c.3438G>T p.L1146= | Silent (SNP) | VAF 44/405 reads (11%) | called by muse, mutect2, varscan2
- TARS1 | c.1287A>G p.E429= | Silent (SNP) | VAF 38/296 reads (13%) | catalogued as rs540151148; called by muse, mutect2, varscan2
- TCAF1 | c.447C>A p.L149= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as COSV100584621; called by muse, mutect2
- TNKS2 | c.2277G>A p.Q759= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- TRGV9 | c.15C>T p.L5= | Silent (SNP) | VAF 38/382 reads (10%) | called by muse, mutect2
- TRMU | c.819G>C p.L273= | Silent (SNP) | VAF 91/561 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.12486T>C p.A4162= (on ENST00000591111; = p.A4116= on NM_003319.4) | Silent (SNP) | VAF 34/276 reads (12%) | catalogued as COSV100629400; called by muse, mutect2, varscan2
- TTN | c.6294G>A p.R2098= (on ENST00000591111; = p.R2052= on NM_003319.4) | Silent (SNP) | VAF 41/456 reads (9%) | catalogued as rs752539323, COSV59933954; called by muse, mutect2
- TUB | c.1425G>A p.E475= (on ENST00000299506 / NM_177972.3; = p.E530= on NM_003320.4) | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as COSV55108082; called by muse, mutect2, varscan2
- USH2A | c.186C>T p.D62= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV56413410; called by muse, mutect2
- UTS2B | c.85C>A p.R29= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.162C>T p.S54= | Silent (SNP) | VAF 160/428 reads (37%) | catalogued as rs1036434944; called by muse, mutect2, varscan2
- ZFHX4 | c.10257A>C p.V3419= | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- ZHX2 | c.780C>T p.V260= | Silent (SNP) | VAF 27/288 reads (9%) | catalogued as rs1379313443; called by muse, mutect2
- ZKSCAN4 | c.1395G>A p.G465= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs775745558; called by muse, mutect2, varscan2
- ZNF737 | c.1209C>T p.G403= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as rs373070943; called by muse, mutect2
- ZNF831 | c.2013C>A p.V671= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- ZNF835 | c.1218A>T p.I406= | Silent (SNP) | VAF 81/606 reads (13%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1136A>T | RNA (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- AC092865.4 | chr12:8390609 C>T | 5'Flank (SNP) | VAF 18/139 reads (13%) | catalogued as rs1301668287; called by muse, mutect2, varscan2
- AC116351.1 | n.910C>G | RNA (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- AL583829.1 | n.468+7400G>C | Intron (SNP) | VAF 42/187 reads (22%) | called by muse, mutect2, varscan2
- CYP21A1P | n.1416G>T | RNA (SNP) | VAF 89/987 reads (9%) | called by muse, mutect2
- CYP21A1P | n.1417G>T | RNA (SNP) | VAF 88/996 reads (9%) | called by muse, mutect2
- FAAH | c.*29del | 3'UTR (DEL) | VAF 42/436 reads (10%) | called by mutect2, pindel, varscan2
- HAS2 | c.*88A>G | 3'UTR (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656315 G>A | 3'Flank (SNP) | VAF 44/548 reads (8%) | catalogued as rs779705886; called by muse, mutect2
- INTS11 | c.429+42C>G | Intron (SNP) | VAF 28/293 reads (10%) | called by muse, mutect2, varscan2
- LILRB1 | c.1800+395C>G | Intron (SNP) | VAF 35/297 reads (12%) | called by muse, mutect2, varscan2
- LINC00967 | n.1057G>A | RNA (SNP) | VAF 35/442 reads (8%) | catalogued as rs577691542; called by muse, mutect2
- MIR508 | n.77G>T | RNA (SNP) | VAF 9/64 reads (14%) | catalogued as rs1557102611; called by muse, mutect2, varscan2
- MOGAT3 | chr7:101202225 G>C | 5'Flank (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- MRPL2 | c.96+39G>A | Intron (SNP) | VAF 50/389 reads (13%) | catalogued as rs746004079; called by muse, mutect2, varscan2
- NDUFS2 | c.628-27C>A | Intron (SNP) | VAF 46/511 reads (9%) | called by muse, mutect2
- NOS1AP | c.454-1285G>A | Intron (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- NR2F2-AS1 | n.894C>G | RNA (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- NR4A3 | c.1254+21C>G | Intron (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- NXPH4 | c.-62C>T | 5'UTR (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2
- OFCC1 | n.2081A>G | RNA (SNP) | VAF 28/293 reads (10%) | called by muse, mutect2
- OR2A13P | n.600T>A | RNA (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- OR5E1P | n.416G>T | RNA (SNP) | VAF 11/98 reads (11%) | catalogued as rs980205772; called by muse, mutect2, varscan2
- OR6W1P | n.468C>T | RNA (SNP) | VAF 42/276 reads (15%) | called by muse, mutect2, varscan2
- OR7D1P | n.649T>C | RNA (SNP) | VAF 48/303 reads (16%) | called by muse, mutect2, varscan2
- PCNP | c.-12G>T | 5'UTR (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- PEG10 | c.*1088G>T | 3'UTR (SNP) | VAF 35/162 reads (22%) | catalogued as COSV71788379; called by muse, mutect2, varscan2
- PPP5D1 | n.769G>T | RNA (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- PTENP1 | n.1105C>T | RNA (SNP) | VAF 24/210 reads (11%) | catalogued as rs1416902697; called by muse, mutect2, varscan2
- RGS22 | c.-32C>A | 5'UTR (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159852 G>A | 5'Flank (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159901 A>T | 5'Flank (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- RUNX1T1 | c.1280-3858T>A | Intron (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2, varscan2
- SATB2 | c.347-15998C>A | Intron (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- SBF1 | c.-177G>T | 5'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SPACA7 | c.*5G>T | 3'UTR (SNP) | VAF 24/180 reads (13%) | catalogued as COSV99366924; called by muse, mutect2, varscan2
- SSX6P | n.148G>A | RNA (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- TMEM135 | c.*698del | 3'UTR (DEL) | VAF 32/288 reads (11%) | called by mutect2, pindel, varscan2
- TSGA10 | c.-485+325G>C | Intron (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.6508+35T>C | Intron (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- USH2A | c.*8A>G | 3'UTR (SNP) | VAF 54/444 reads (12%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438640 C>T | 5'Flank (SNP) | VAF 56/485 reads (12%) | called by muse, mutect2, varscan2
- YAF2 | c.152+26969A>G | Intron (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
